Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A4V2, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A4V2-01A (Primary Tumor).

[page 1 of 2]
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

Papillary carcinoma of right tracheal right FNA and (+) for papillary. Right thyroid nodule. Rule out malignancy.

Specimens Submitted:

- 1: Right thyroid and isthmus, right hemithyroidectomy
- 2: Left thyroid and isthmus, left hemithyroidectomy

DIAGNOSIS:

1. Right thyroid and isthmus, right hemithyroidectomy:

Part # 1

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 3.0 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Adenoma(s) (away from the carcinoma):

Not identified

Non-Neoplastic Thyroid:

ICD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9

fw
10/27/12

[page 2 of 2]
exhibits chronic inflammation
Parathyroid Glands:
Not identified

Lymph Nodes:
One benign lymph node (0/1)

2. Left thyroid and isthmus, left hemithyroidectomy:
- Nodular hyperplasia
- No parathyroid gland identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh and is labeled "right thyroid and isthmus". It consists of a thyroid lobe measuring 5 x 3 x 1.5 cm (right lobe) with isthmus (1.2 x 1.0 x 0.5 cm) and weighing 16.5 g. The specimen is oriented by a long stitch designating the upper pole and a short stitch designating the isthmus. The specimen is inked as follows: anterior-blue and posterior-black. The specimen is serially sectioned revealing a well-circumscribed, well encapsulated nodule with focal areas of necrosis situated in the right lobe extending from the upper to the mid-portion of the lobe. The nodule measures 3.0 x 2.5 x 1.5 cm. The specimen is entirely submitted. A representative portion of the nodule has been submitted for TPS.

Summary of sections:

N - nodule
RL - right lobe
I - isthmus

2. The specimen is received fresh and is labeled "left thyroid and isthmus". It consists of a thyroid lobe measuring 4 x 2 x 0.8 cm (left lobe) with isthmus (1.0 x 1.0 x 0.5 cm) and weighing 5 g. The specimen is oriented by a long stitch designating the upper pole and a short stitch designating the isthmus. The specimen is inked as follows: anterior-blue and posterior-black. The specimen is serially sectioned revealing a tan/red unremarkable cut-surface. The specimen is entirely submitted.

Summary of sections:

LL - left lobe
I - isthmus

Summary of Sections:

Part 1: Right thyroid and isthmus, right hemithyroidectomy

Block	Sect. Site	PCs
1	I	1
10	N	10
2	RL	2

Part 2: Left thyroid and isthmus, left hemithyroidectomy

Block	Sect. Site	PCs
1	I	1
4	LL	4

10/12/12

Source: NCI Genomic Data Commons file d1d149a0-1aaa-4404-93af-7717df8eb4d2 (TCGA-DJ-A4V2.02145821-EB2F-4F21-98C7-379353CF81E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).